Somatic mutation profile of tumor specimen C3N-03054-01 (aliquot CPT0236060006) from CPTAC case C3N-03054, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA3; Tumor grade: G2; Age at diagnosis: 72.9 years (26,640 days).
Specimen C3N-03054-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 405dcbee-f9c9-4489-a6bc-491e51ba0880.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03054-31 (Blood Derived Normal), aliquot CPT0236120002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1be008b-139d-47fc-be0a-367e7fda1006

The open-access MAF lists 47 somatic variants for this specimen: 31 protein-altering or splice-affecting, 9 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 9, 5'UTR 2, Nonsense Mutation 2, Splice Region 2, 3'Flank 2, Intron 1, Splice Site 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC124067.2 | n.294+1G>A | Splice Site (SNP) | VAF 14/284 reads (5%) | catalogued as rs1433668343; called by muse, mutect2
- BRCA2 | c.5344C>G p.Q1782E | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs80358757, CM067354; ClinVar: uncertain significance; called by muse, mutect2
- CCDC33 | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 17/332 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.424); catalogued as rs940462787; called by muse, mutect2
- CLK1 | c.330A>T p.R110S | Missense Mutation (SNP) | VAF 48/346 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs779669445; called by muse, mutect2, varscan2
- COLGALT1 | c.1438G>T p.A480S | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.05); catalogued as COSV53110971; called by muse, mutect2
- DMD | c.5858G>T p.S1953I | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as CD014993; called by muse, mutect2
- EIF2AK1 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.695); catalogued as rs756091057, COSV99551403; called by muse, mutect2
- GK2 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 9/238 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.631); catalogued as COSV62626108; called by muse, mutect2
- PM20D1 | c.436C>A p.R146S | Missense Mutation (SNP) | VAF 43/440 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0.111); catalogued as COSV65649095; called by muse, mutect2
- PRB3 | c.178C>T p.R60* | Nonsense Mutation (SNP) | VAF 42/414 reads (10%) | catalogued as rs763857405; called by muse, mutect2
- SPTA1 | c.4957G>C p.E1653Q | Missense Mutation (SNP) | VAF 16/584 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as COSV63756950; called by muse, mutect2
- SYNDIG1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763909114, COSV65234546; called by muse, mutect2
- SYNGAP1 | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1561785594; called by muse, mutect2
- CNOT7 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 10/177 reads (6%) | called by muse, mutect2
- GIMAP1 | c.190A>G p.R64G | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.151); called by muse, mutect2
- GOLGB1 | c.3460A>T p.S1154C | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.614); called by muse, mutect2
- ITGAM | c.3167G>T p.W1056L (on ENST00000648685 / NM_001145808.2; = p.W1055L on NM_000632.4) | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- KRTAP10-4 | c.1022A>G p.Q341R | Missense Mutation (SNP) | VAF 25/934 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.266); called by muse, mutect2
- LILRA1 | c.1312+8A>C | Splice Region (SNP) | VAF 20/476 reads (4%) | called by muse, mutect2
- NLGN4X | c.1567G>A p.V523I | Missense Mutation (SNP) | VAF 16/337 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.754); called by muse, mutect2
- NUP160 | c.3829A>T p.I1277F | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.101); called by muse, mutect2
- PCARE | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 32/1109 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2
- PCDHGB6 | c.221A>G p.H74R | Missense Mutation (SNP) | VAF 24/373 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.433); called by muse, mutect2
- PLCH1 | c.4265A>T p.N1422I (on ENST00000340059 / NM_001130960.2; = p.N1414I on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/201 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); called by muse, mutect2
- SLC15A5 | c.1161C>T p.I387= | Splice Region (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- SLC39A13 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 28/510 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.055); called by muse, mutect2
- SPON1 | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); called by muse, mutect2
- TRIM64C | c.328C>G p.L110V | Missense Mutation (SNP) | VAF 23/618 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2
- VCP | c.2389A>G p.T797A | Missense Mutation (SNP) | VAF 80/443 reads (18%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDFY4 | c.9073G>A p.E3025K | Missense Mutation (SNP) | VAF 17/394 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2
- ZNF426 | c.663A>C p.E221D | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.587); called by muse, mutect2
- CDC20 | c.1347G>A p.L449= | Silent (SNP) | VAF 7/157 reads (4%) | called by muse, mutect2
- ERCC6L | c.981G>A p.R327= | Silent (SNP) | VAF 6/89 reads (7%) | called by muse, mutect2
- GFRA3 | c.819T>C p.H273= | Silent (SNP) | VAF 22/438 reads (5%) | called by muse, mutect2
- GPR50 | c.1401C>T p.F467= | Silent (SNP) | VAF 14/213 reads (7%) | called by muse, mutect2
- KMT2B | c.456G>A p.R152= | Silent (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- KRT83 | c.180C>A p.R60= | Silent (SNP) | VAF 31/771 reads (4%) | catalogued as COSV53338538; called by muse, mutect2
- PCDHGA1 | c.1878G>C p.V626= | Silent (SNP) | VAF 27/596 reads (5%) | catalogued as COSV65296437; called by muse, mutect2
- PRRC2C | c.5565C>A p.V1855= (on ENST00000367742; = p.V1853= on NM_015172.4) | Silent (SNP) | VAF 11/301 reads (4%) | called by muse, mutect2
- TCTE1 | c.352C>T p.L118= | Silent (SNP) | VAF 20/180 reads (11%) | catalogued as rs750932871; called by muse, mutect2, varscan2
- C14orf132 | chr14:96090659 G>C | 3'Flank (SNP) | VAF 14/378 reads (4%) | called by muse, mutect2
- CTRC | c.-22A>C | 5'UTR (SNP) | VAF 42/614 reads (7%) | called by muse, mutect2
- DNA2 | chr10:68472081 T>G | 5'Flank (SNP) | VAF 4/74 reads (5%) | catalogued as rs1269132099; called by muse, mutect2
- HNRNPA2B1 | c.-1G>C | 5'UTR (SNP) | VAF 12/367 reads (3%) | catalogued as COSV100523039; called by muse, mutect2
- PRCD | chr17:76544698 A>C | 3'Flank (SNP) | VAF 38/779 reads (5%) | called by muse, mutect2
- PRKAG2 | c.115-20952C>T | Intron (SNP) | VAF 12/446 reads (3%) | catalogued as rs1430875958; called by muse, mutect2
- RRN3P1 | n.3043C>T | RNA (SNP) | VAF 44/140 reads (31%) | called by mutect2, varscan2
